Somatic mutation profile of tumor specimen TCGA-UF-A7JC-01A (aliquot TCGA-UF-A7JC-01A-21D-A34J-08) from TCGA case TCGA-UF-A7JC, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 42.3 years (15,452 days).
Specimen TCGA-UF-A7JC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c02a0d82-8602-44cd-977d-5f5a04ad2662.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UF-A7JC-10A (Blood Derived Normal), aliquot TCGA-UF-A7JC-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/248b6ae4-4e0a-42c2-9e7c-cacee3906e3b

The open-access MAF lists 60 somatic variants for this specimen: 46 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 10, In Frame Del 3, RNA 2, Splice Region 1, 5'UTR 1, Intron 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 35/53 reads (66%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV61684095, COSV61696676; called by muse, mutect2, varscan2
- AC008397.2 | c.299G>A p.S100N | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.11); catalogued as COSV99441265; called by muse, mutect2
- ALS2 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 55/98 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99968842; called by muse, mutect2, varscan2
- BBS4 | c.1171G>T p.A391S | Missense Mutation (SNP) | VAF 69/299 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.431); catalogued as COSV99166387; called by muse, mutect2, varscan2
- DACH1 | c.2146A>G p.T716A (on ENST00000619232 / NM_001366712.1; = p.T462A on NM_004392.6) | Missense Mutation (SNP) | VAF 195/645 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as COSV100497612; called by muse, mutect2, varscan2
- DEFB116 | c.185C>A p.P62Q | Missense Mutation (SNP) | VAF 145/460 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.025); catalogued as rs774121307, COSV101269211; called by muse, mutect2, varscan2
- DISP3 | c.599G>A p.S200N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV99607530; called by muse, mutect2, varscan2
- DISP3 | c.2664G>A p.M888I | Missense Mutation (SNP) | VAF 146/361 reads (40%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV99607537; called by muse, mutect2, varscan2
- DLGAP5 | c.532G>T p.G178C | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV99903670; called by muse, mutect2, varscan2
- FMN2 | c.5153T>C p.I1718T | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV100143169; called by muse, mutect2, varscan2
- FNIP1 | c.2088G>T p.E696D | Missense Mutation (SNP) | VAF 163/236 reads (69%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV100330281; called by muse, mutect2, varscan2
- GCN1 | c.5344A>G p.I1782V | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.932); catalogued as rs1020552617, COSV100324717; called by muse, mutect2, varscan2
- HOXD9 | c.932C>T p.T311I | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1347178931, COSV99981745; called by muse, mutect2, varscan2
- KRT4 | c.908A>G p.D303G | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99542698; called by muse, mutect2, varscan2
- KYAT3 | c.485A>G p.Y162C | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373497698; called by muse, mutect2, varscan2
- LAMTOR2 | c.66C>T p.T22= | Splice Region (SNP) | VAF 18/34 reads (53%) | catalogued as COSV100849071; called by muse, mutect2, varscan2
- MRPL51 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 215/719 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV99975186; called by muse, mutect2, varscan2
- MYH15 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 89/139 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99842389; called by muse, mutect2, varscan2
- MYH8 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as COSV101238267; called by muse, mutect2, varscan2
- NPAP1 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs770374390, COSV100274841, COSV61512825; called by muse, varscan2
- NXPE4 | c.1503C>A p.D501E (on ENST00000375478 / NM_001077639.2; = p.D217E on NM_017678.3) | Missense Mutation (SNP) | VAF 83/114 reads (73%) | SIFT tolerated (0.13); PolyPhen benign (0.075); catalogued as COSV100970317; called by muse, mutect2, varscan2
- NYAP1 | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141511133; called by muse, mutect2, varscan2
- OR10G3 | c.850C>A p.L284I | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as COSV100336066; called by muse, mutect2, varscan2
- OSBP | c.1459A>G p.T487A | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99802715; called by muse, mutect2, varscan2
- PPP1R26 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 90/203 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs149000148; called by muse, mutect2, varscan2
- PSMA3 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99373321; called by muse, mutect2, varscan2
- PTPRK | c.3403C>T p.H1135Y (on ENST00000368215 / NM_001291984.2; = p.H1136Y on NM_002844.4) | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs778539463, COSV100950465; called by muse, mutect2, varscan2
- SAFB | c.1771G>A p.D591N | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99412546; called by muse, mutect2, varscan2
- SAFB | c.1772A>C p.D591A | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV52653514, COSV99412547; called by muse, mutect2, varscan2
- SCAI | c.1379C>T p.A460V (on ENST00000336505 / NM_001144877.3; = p.A483V on NM_173690.5) | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100332296; called by muse, mutect2, varscan2
- SCARF1 | c.1244-1G>A p.X415_splice | Splice Site (SNP) | VAF 32/75 reads (43%) | catalogued as COSV99556902; called by muse, mutect2, varscan2
- SEC16A | c.5807C>A p.P1936H | Missense Mutation (SNP) | VAF 2/16 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99256418; called by muse, mutect2
- SLC12A4 | c.1708C>T p.L570F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV100311315; called by muse, mutect2, varscan2
- SLF2 | c.296C>G p.S99C | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.545); catalogued as COSV99488577; called by muse, mutect2, varscan2
- SPTA1 | c.5749A>G p.I1917V | Missense Mutation (SNP) | VAF 125/264 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV100934419; called by muse, mutect2, varscan2
- TIMP1 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 39/49 reads (80%) | SIFT tolerated (0.19); PolyPhen benign (0.293); catalogued as COSV99512118; called by muse, mutect2, varscan2
- TRRAP | c.574A>G p.M192V | Missense Mutation (SNP) | VAF 108/230 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.267); catalogued as COSV100722067; called by muse, mutect2, varscan2
- TTN | c.41688G>T p.Q13896H (on ENST00000591111; = p.Q6472H on NM_003319.4) | Missense Mutation (SNP) | VAF 87/239 reads (36%) | PolyPhen probably damaging (0.997); catalogued as rs727503625, COSV100596847; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- U2SURP | c.95A>T p.D32V | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.954); catalogued as COSV101204353; called by muse, mutect2, varscan2
- ZNF30 | c.1362A>C p.K454N | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as COSV100340362; called by muse, mutect2, varscan2
- ZRSR2 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.741); catalogued as COSV100236864, COSV57065470; called by muse, mutect2, varscan2
- BTK | c.1244_1248dup p.K417* | Nonsense Mutation (INS) | VAF 231/320 reads (72%) | called by mutect2, pindel, varscan2
- EFTUD2 | c.2253_2255del p.S752del | In Frame Del (DEL) | VAF 47/152 reads (31%) | called by mutect2, pindel, varscan2
- LONP1 | c.2663_2665del p.K888del | In Frame Del (DEL) | VAF 27/84 reads (32%) | called by mutect2, pindel, varscan2
- PRIMA1 | c.441_458del p.D147_V153delinsE | In Frame Del (DEL) | VAF 20/72 reads (28%) | called by mutect2, pindel, varscan2
- TRAJ10 | c.61C>A p.L21I | Missense Mutation (SNP) | VAF 51/194 reads (26%) | called by muse, mutect2, varscan2
- ABL2 | c.3162G>A p.S1054= (on ENST00000502732 / NM_007314.4; = p.S1039= on NM_005158.5) | Silent (SNP) | VAF 36/137 reads (26%) | catalogued as rs148651616; called by muse, mutect2, varscan2
- CDH9 | c.567C>A p.A189= | Silent (SNP) | VAF 52/132 reads (39%) | catalogued as COSV99141983; called by muse, mutect2, varscan2
- COL27A1 | c.4686G>T p.G1562= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV100620751, COSV61924029; called by muse, mutect2, varscan2
- HERC2 | c.14349C>T p.Y4783= | Silent (SNP) | VAF 40/112 reads (36%) | catalogued as rs768941431, COSV55327016; called by muse, mutect2, varscan2
- HMCES | c.999C>G p.L333= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as COSV101077252; called by muse, mutect2, varscan2
- KIF26B | c.2328G>A p.A776= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as rs766252476, COSV63642461; called by muse, mutect2, varscan2
- PGM2L1 | c.1554A>G p.K518= | Silent (SNP) | VAF 225/359 reads (63%) | catalogued as rs760272235, COSV99994619; called by muse, mutect2, varscan2
- SEC16A | c.5808T>G p.P1936= | Silent (SNP) | VAF 2/16 reads (13%) | catalogued as COSV99256414; called by muse, mutect2
- SFSWAP | c.1536C>T p.G512= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as rs1232358326, COSV55527237; called by muse, mutect2, varscan2
- ZFAND4 | c.1440A>G p.P480= | Silent (SNP) | VAF 94/320 reads (29%) | catalogued as COSV100762877; called by muse, mutect2, varscan2
- COPS9 | c.-4C>T | 5'UTR (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100108769; called by muse, mutect2
- SLCO1B3-SLCO1B7 | c.1866-18510A>T | Intron (SNP) | VAF 24/62 reads (39%) | catalogued as COSV101043039; called by muse, mutect2, varscan2
- SSPOP | n.6706G>A | RNA (SNP) | VAF 13/28 reads (46%) | catalogued as COSV100022182; called by muse, mutect2, varscan2
- TUBB7P | n.209C>A | RNA (SNP) | VAF 115/137 reads (84%) | called by muse, mutect2, varscan2
